Somatic mutation profile of tumor specimen TCGA-63-A5MB-01A (aliquot TCGA-63-A5MB-01A-11D-A26M-08) from TCGA case TCGA-63-A5MB, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB.
Specimen TCGA-63-A5MB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66405115-9e54-4e9f-b21a-e38d24dfa969.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-63-A5MB-10A (Blood Derived Normal), aliquot TCGA-63-A5MB-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d340e26-4c72-46c5-9ecf-46b37cbd31c7

The open-access MAF lists 374 somatic variants for this specimen: 284 protein-altering or splice-affecting, 78 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 243, Silent 78, Nonsense Mutation 21, Frame Shift Del 13, 5'Flank 4, Frame Shift Ins 4, 3'Flank 3, RNA 3, In Frame Del 2, Splice Site 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.92G>T p.G31V | Missense Mutation (SNP) | VAF 19/29 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67959995, COSV67960100, COSV67961494; called by muse, mutect2, varscan2
- TP53 | c.751A>T p.I251F | Missense Mutation (SNP) | VAF 33/53 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM114005, COSV52677403, COSV52702261, COSV52772679, COSV52927118; called by muse, mutect2, varscan2
- ABCC2 | c.2330A>G p.Q777R | Missense Mutation (SNP) | VAF 33/53 reads (62%) | SIFT tolerated (0.13); PolyPhen benign (0.348); catalogued as COSV100966564; called by muse, mutect2, varscan2
- AC098582.1 | c.496C>G p.H166D | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV99985674; called by muse, mutect2, varscan2
- ACSM2A | c.1308C>A p.N436K (on ENST00000219054; = p.N357K on NM_001308169.2) | Missense Mutation (SNP) | VAF 85/110 reads (77%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as rs775717868, COSV54587253; called by muse, mutect2, varscan2
- ACTR2 | c.905T>C p.V302A | Missense Mutation (SNP) | VAF 19/204 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99573943; called by muse, mutect2
- ADARB2 | c.2133G>C p.Q711H | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.201); catalogued as COSV101184558; called by muse, mutect2, varscan2
- ADCY1 | c.723G>T p.K241N | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV52039029; called by muse, mutect2, varscan2
- ADCY2 | c.2812A>G p.I938V | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100603057; called by muse, mutect2, varscan2
- ADGRB1 | c.268C>G p.P90A | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100029797; called by muse, mutect2, varscan2
- ADPRH | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100813325; called by muse, mutect2, varscan2
- AGBL5 | c.385G>C p.E129Q | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.622); catalogued as COSV100549161; called by muse, mutect2, varscan2
- AKAP13 | c.3605C>T p.S1202L | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as COSV100774812, COSV63456649; called by muse, mutect2, varscan2
- AKR1D1 | c.753C>A p.Y251* | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | catalogued as rs761306601, COSV99653123; called by muse, mutect2, varscan2
- ALDH16A1 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 83/246 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as rs151226186; called by muse, mutect2, varscan2
- ALK | c.350C>G p.P117R | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.415); catalogued as rs201290745, COSV101202159; ClinVar: uncertain significance; called by muse, varscan2
- ANK1 | c.253G>T p.A85S | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99225568; called by muse, mutect2, varscan2
- APOF | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV100028955, COSV58474483; called by muse, mutect2, varscan2
- APOOL | c.167A>T p.E56V | Missense Mutation (SNP) | VAF 31/42 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100920869; called by muse, mutect2, varscan2
- APP | c.1874G>A p.G625E | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.98); PolyPhen possibly damaging (0.632); catalogued as COSV100695883; called by muse, mutect2, varscan2
- ARHGAP17 | c.1423G>C p.G475R | Missense Mutation (SNP) | VAF 77/129 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51513143, COSV99253570; called by muse, mutect2, varscan2
- ARL6IP6 | c.331A>G p.I111V | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1366694757, COSV100424027; called by muse, mutect2, varscan2
- ARMC10 | c.829C>T p.L277F | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100085774, COSV58523731; called by muse, mutect2
- ASTN2 | c.686C>A p.A229D | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.601); catalogued as COSV100528223, COSV57830346; called by muse, mutect2, varscan2
- AXDND1 | c.2272T>A p.Y758N | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100858467; called by muse, mutect2
- BLM | c.524G>T p.S175I | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV100757229; called by muse, mutect2, varscan2
- BMP4 | c.795G>T p.W265C | Missense Mutation (SNP) | VAF 44/71 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99816995; called by muse, mutect2, varscan2
- BOD1L1 | c.7043A>G p.E2348G | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99239588; called by muse, mutect2, varscan2
- C10orf88 | c.709A>T p.M237L | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100925025; called by muse, mutect2, varscan2
- C2CD3 | c.1235G>T p.G412V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.033); catalogued as COSV100486870; called by muse, mutect2, varscan2
- C7 | c.304G>A p.V102I | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100495949; called by muse, mutect2, varscan2
- CACNA1B | c.939G>T p.M313I | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99497973; called by muse, mutect2, varscan2
- CACNA1C | c.2244C>A p.F748L | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100219471; called by muse, mutect2, varscan2
- CACNA1E | c.5665C>T p.Q1889* | Nonsense Mutation (SNP) | VAF 15/18 reads (83%) | catalogued as COSV100703156; called by muse, mutect2, varscan2
- CACNA1S | c.4064A>T p.N1355I | Missense Mutation (SNP) | VAF 94/138 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as COSV100755082; called by muse, mutect2, varscan2
- CACNG8 | c.304G>C p.V102L | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.236); catalogued as COSV99555031; called by muse, mutect2, varscan2
- CALCRL | c.158T>G p.M53R | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV101130979; called by muse, mutect2, varscan2
- CAMK2D | c.793G>C p.E265Q | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated, low confidence (0.52); PolyPhen possibly damaging (0.646); catalogued as COSV99594153; called by muse, mutect2, varscan2
- CCDC173 | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs867435915, COSV99644631; called by muse, mutect2, varscan2
- CCDC65 | c.369T>A p.N123K | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); catalogued as COSV99908090; called by muse, mutect2
- CCT8L2 | c.277G>C p.A93P | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100742822; called by muse, mutect2, varscan2
- CD163L1 | c.2860T>C p.Y954H | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.066); catalogued as COSV100550174; called by muse, mutect2
- CEP76 | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 55/109 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.178); catalogued as COSV100042848; called by muse, mutect2, varscan2
- CEP83 | c.58G>A p.G20R | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.847); catalogued as COSV100352910; called by muse, mutect2, varscan2
- CFAP47 | c.5147T>C p.V1716A | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV100545429; called by muse, mutect2, varscan2
- CLDN25 | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 52/109 reads (48%) | catalogued as COSV101493605; called by muse, mutect2, varscan2
- CLSTN2 | c.1843T>C p.C615R | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs776915256, COSV101515795; called by mutect2, varscan2
- CMAS | c.665G>C p.R222T | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.629); catalogued as COSV99982682; called by muse, mutect2
- COL12A1 | c.2123G>C p.G708A | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV100486109; called by muse, mutect2, varscan2
- COL20A1 | c.818C>A p.A273E | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV100490707; called by muse, varscan2
- CRX | c.344G>T p.R115L | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as CM016127, COSV99704541; called by muse, mutect2, varscan2
- CRYBA1 | c.79T>A p.S27T | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV99837028; called by muse, mutect2, varscan2
- CSNK1G1 | c.680-1G>T p.X227_splice | Splice Site (SNP) | VAF 29/50 reads (58%) | catalogued as COSV100274228, COSV57309565; called by muse, mutect2, varscan2
- CSTL1 | c.416A>G p.H139R | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV99851163; called by muse, mutect2, varscan2
- CUL9 | c.4498C>G p.R1500G | Missense Mutation (SNP) | VAF 22/430 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as COSV52732560, COSV99335516; called by muse, mutect2
- CYP4F22 | c.66C>A p.Y22* | Nonsense Mutation (SNP) | VAF 33/104 reads (32%) | catalogued as COSV99512851; called by muse, mutect2, varscan2
- DCBLD2 | c.296G>A p.C99Y | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100472488; called by muse, mutect2, varscan2
- DCC | c.407T>C p.V136A | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100500651; called by muse, mutect2, varscan2
- DELE1 | c.144C>A p.D48E | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99519855; called by muse, mutect2
- DEPDC1B | c.993G>C p.M331I | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV99409675; called by muse, mutect2, varscan2
- DGCR8 | c.1913C>T p.S638F | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV100708005; called by muse, mutect2, varscan2
- DMBT1 | c.5062C>A p.P1688T (on ENST00000338354 / NM_001377530.1; = p.P931T on NM_004406.3) | Missense Mutation (SNP) | VAF 140/272 reads (51%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV100353200; called by muse, mutect2, varscan2
- DNAH17 | c.1204G>T p.E402* | Nonsense Mutation (SNP) | VAF 10/19 reads (53%) | catalogued as COSV101102548; called by muse, varscan2
- DNAH8 | c.10789A>G p.I3597V | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100545781; called by muse, mutect2, varscan2
- DTX2 | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.079); catalogued as rs764883046, COSV56859892; called by muse, mutect2, varscan2
- ECM1 | c.583C>A p.L195I | Missense Mutation (SNP) | VAF 44/368 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100682031; called by muse, mutect2, varscan2
- EML1 | c.1288G>A p.G430S | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs763202236, COSV51751799, COSV99215146; called by muse, mutect2, varscan2
- EPHA3 | c.305C>A p.T102N | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100345881; called by muse, mutect2, varscan2
- EYA4 | c.1134T>G p.F378L (on ENST00000531901 / NM_001301013.1; = p.F372L on NM_004100.5) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as COSV100765966; called by muse, mutect2, varscan2
- FAM20B | c.844G>T p.D282Y | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV99762414; called by muse, mutect2, varscan2
- FAT4 | c.7423A>T p.T2475S | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as COSV100628885; called by muse, mutect2, varscan2
- FCHO2 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV99821527, COSV99821840; called by muse, mutect2, varscan2
- FHL5 | c.845C>T p.T282I | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.077); catalogued as COSV58735689; called by muse, mutect2, varscan2
- FLI1 | c.829G>T p.G277* | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | catalogued as COSV99857841; called by muse, mutect2, varscan2
- FLNC | c.2746C>T p.R916W | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs762095761, COSV100368240; called by muse, mutect2, varscan2
- FNBP1 | c.824G>C p.G275A | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100852724; called by muse, mutect2, varscan2
- FNDC3A | c.2819G>T p.S940I (on ENST00000492622 / NM_001079673.2; = p.S884I on NM_014923.5) | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101256762; called by muse, mutect2, varscan2
- FOLH1 | c.1289G>T p.G430V | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99923339; called by muse, mutect2, varscan2
- FSTL5 | c.1700C>A p.T567K | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV100056573; called by muse, mutect2, varscan2
- GABRG1 | c.1322C>A p.S441Y | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); catalogued as COSV54958964, COSV99778198; called by muse, mutect2, varscan2
- GALNT13 | c.872C>A p.A291D | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV101223214; called by muse, mutect2, varscan2
- GATA6 | c.411C>A p.S137R | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV99333225; called by muse, mutect2, varscan2
- GLRA4 | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 24/37 reads (65%) | catalogued as COSV101009653; called by muse, mutect2, varscan2
- GRID1 | c.2342G>T p.R781M | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100024465; called by muse, mutect2, varscan2
- GRIK2 | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100026847; called by muse, varscan2
- GRM8 | c.2063A>G p.K688R | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100283549; called by muse, mutect2, varscan2
- GTF2F1 | c.1240G>T p.V414L | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV99831754; called by muse, mutect2, varscan2
- HAO1 | c.573A>T p.L191F | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.121); catalogued as rs199630444, COSV101113230; called by muse, mutect2
- HEXA | c.1156G>C p.D386H | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99173758; called by muse, mutect2
- HIVEP3 | c.4867A>G p.R1623G | Missense Mutation (SNP) | VAF 52/89 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV99912910; called by muse, mutect2, varscan2
- HSD17B7 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.129); catalogued as rs373109770; called by muse, mutect2, varscan2
- HTR3B | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99492035; called by muse, mutect2, varscan2
- ICAM1 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99320897; called by muse, mutect2, varscan2
- IFT80 | c.2291C>A p.S764* | Nonsense Mutation (SNP) | VAF 33/111 reads (30%) | catalogued as COSV100424829; called by muse, mutect2, varscan2
- IGF1R | c.816G>C p.E272D | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV99151656; called by muse, mutect2, varscan2
- IGF2R | c.4408A>G p.T1470A | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.08); PolyPhen benign (0.426); catalogued as rs1010570643, COSV100807518; called by muse, mutect2, varscan2
- IKZF1 | c.943A>T p.I315F | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.995); catalogued as COSV100498470; called by muse, mutect2, varscan2
- IL17RA | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as rs561912993, COSV100083195, COSV100083332, COSV60051745; called by muse, mutect2, varscan2
- IRF8 | c.455T>A p.V152E | Missense Mutation (SNP) | VAF 78/153 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV51897947, COSV99236544; called by muse, mutect2, varscan2
- ITGB2 | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT tolerated (0.15); PolyPhen benign (0.102); catalogued as COSV100185920; called by muse, mutect2, varscan2
- ITPRID1 | c.2492A>G p.H831R | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as COSV100086609; called by muse, mutect2, varscan2
- KCNA6 | c.1504C>A p.P502T | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV54976401, COSV99768488; called by muse, mutect2, varscan2
- KCTD8 | c.104G>A p.G35E | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.029); catalogued as COSV100759640; called by muse, mutect2, varscan2
- KDM8 | c.219C>A p.D73E | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.659); catalogued as COSV99619672; called by muse, mutect2, varscan2
- KLB | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as rs750040544, COSV99962221; called by muse, mutect2, varscan2
- KLHL6 | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 40/371 reads (11%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.088); catalogued as COSV100384732; called by muse, mutect2, varscan2
- KLHL7 | c.325G>A p.V109M (on ENST00000339077 / NM_001031710.3; = p.V61M on NM_018846.5) | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as COSV100178135; called by muse, mutect2
- KLRF1 | c.486G>T p.Q162H | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV99684414; called by muse, mutect2, varscan2
- KRIT1 | c.1621A>T p.K541* | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | catalogued as COSV100388801; called by muse, mutect2, varscan2
- KRTAP11-1 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1487939587, COSV100190663, COSV60093946; called by muse, mutect2, varscan2
- LGALS9 | c.994C>T p.R332C (on ENST00000395473 / NM_009587.3; = p.R300C on NM_002308.4) | Missense Mutation (SNP) | VAF 56/454 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as rs1176776874, COSV56349973; called by muse, mutect2, varscan2
- LIFR | c.2045C>A p.T682N | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV99664445; called by muse, mutect2, varscan2
- LMNB2 | c.1694T>A p.V565D | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV99296008; called by muse, mutect2
- LMO1 | c.436C>A p.Q146K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100230961; called by muse, mutect2, varscan2
- LPAR4 | c.608A>T p.K203M | Missense Mutation (SNP) | VAF 27/33 reads (82%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV101425134, COSV70912924; called by muse, mutect2, varscan2
- LRG1 | c.963G>A p.M321I | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.292); catalogued as rs774662269, COSV56702590; called by muse, mutect2, varscan2
- LRGUK | c.1295A>G p.H432R | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.827); catalogued as rs758180099, COSV99604307; called by muse, mutect2, varscan2
- LRRC8A | c.650C>A p.S217* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | catalogued as COSV99396676; called by muse, mutect2, varscan2
- LRRK2 | c.4885A>T p.R1629* | Nonsense Mutation (SNP) | VAF 26/72 reads (36%) | catalogued as COSV100110436; called by muse, mutect2
- LY9 | c.720G>C p.Q240H | Missense Mutation (SNP) | VAF 62/426 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.671); catalogued as COSV99626867; called by muse, mutect2, varscan2
- LYAR | c.359A>T p.N120I | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100603502; called by muse, mutect2, varscan2
- MAGEL2 | c.2570C>A p.A857D | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.931); catalogued as COSV100045989; called by muse, mutect2, varscan2
- MAMDC4 | c.2926G>C p.E976Q (on ENST00000445819; = p.E897Q on NM_206920.3) | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.873); catalogued as COSV99808084; called by muse, mutect2, varscan2
- MAP3K1 | c.2837del p.T946Kfs*22 | Frame Shift Del (DEL) | VAF 23/37 reads (62%) | catalogued as COSV101266900; called by mutect2, varscan2*
- MCHR2 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867857457, COSV99912157; called by muse, mutect2, varscan2
- MDGA2 | c.2147G>C p.R716T (on ENST00000399232 / NM_001113498.2; = p.R418T on NM_182830.4) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as COSV100637385; called by muse, mutect2, varscan2
- MET | c.814C>T p.Q272* | Nonsense Mutation (SNP) | VAF 7/129 reads (5%) | catalogued as COSV100577245; called by muse, mutect2
- MFAP5 | c.236dup p.N79Kfs*9 | Frame Shift Ins (INS) | VAF 34/103 reads (33%) | catalogued as rs746355340; called by mutect2, varscan2
- MGAM | c.4511G>A p.R1504Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs374506553; called by muse, mutect2
- MLLT10 | c.1892C>G p.S631C (on ENST00000307729 / NM_001195626.3; = p.S647C on NM_004641.3) | Missense Mutation (SNP) | VAF 67/101 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV100308250; called by muse, mutect2, varscan2
- MLNR | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.12); PolyPhen benign (0.346); catalogued as rs781121645, COSV99519930; called by muse, varscan2
- MMS22L | c.2806A>C p.S936R | Missense Mutation (SNP) | VAF 28/41 reads (68%) | SIFT tolerated (0.44); PolyPhen benign (0.361); catalogued as COSV51522850, COSV99247109; called by muse, mutect2, varscan2
- MOBP | c.217C>A p.R73S (on ENST00000420739; = p.R97S on NM_001278322.2) | Missense Mutation (SNP) | VAF 7/10 reads (70%) | PolyPhen possibly damaging (0.693); catalogued as COSV100215560; called by muse, varscan2
- MRGPRX1 | c.947C>A p.S316* | Nonsense Mutation (SNP) | VAF 17/51 reads (33%) | catalogued as rs375703928, COSV100246027, COSV57106951; called by muse, mutect2, varscan2
- MRPS7 | c.28C>G p.R10G | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); catalogued as COSV99821622; called by muse, mutect2, varscan2
- MUC4 | c.2074G>T p.A692S | Missense Mutation (SNP) | VAF 55/324 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.374); catalogued as COSV100640714; called by muse, mutect2, varscan2
- MYO5C | c.4111G>C p.E1371Q | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99954883; called by muse, mutect2, varscan2
- NCBP1 | c.175G>T p.A59S | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.145); catalogued as COSV64317182; called by muse, mutect2, varscan2
- NDST4 | c.502A>C p.N168H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.078); catalogued as COSV99996737; called by muse, mutect2, varscan2
- NEU4 | c.581G>T p.S194I (on ENST00000391969 / NM_001167602.3; = p.S206I on NM_080741.4) | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as COSV100372068; called by muse, mutect2, varscan2
- NFX1 | c.1384C>A p.H462N | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100582236; called by muse, mutect2
- NKX2-2 | c.370_371insT p.D124Vfs*186 | Frame Shift Ins (INS) | VAF 11/31 reads (35%) | catalogued as COSV101010588; called by mutect2, varscan2
- NLGN4X | c.545G>T p.G182V | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99322225; called by muse, mutect2, varscan2
- NLRP2 | c.854T>A p.F285Y | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV99672344; called by muse, mutect2, varscan2
- NMRK2 | c.247C>A p.H83N | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV99396378; called by muse, mutect2, varscan2
- NNT | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769414431, COSV52930755; called by muse, mutect2, varscan2
- NPR1 | c.1195G>T p.D399Y | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100903755; called by muse, mutect2, varscan2
- NRXN2 | c.1930G>C p.E644Q | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99634597; called by muse, mutect2, varscan2
- ODAM | c.655G>T p.G219* | Nonsense Mutation (SNP) | VAF 12/19 reads (63%) | catalogued as COSV101258055; called by muse, mutect2, varscan2
- OPRD1 | c.800T>C p.V267A | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1368753821, COSV99330362; called by muse, mutect2, varscan2
- OR11H12 | c.332G>T p.G111V | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1229460288, COSV101612500; called by mutect2, varscan2
- OR2A1 | c.175T>A p.Y59N | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101283397; called by mutect2, varscan2
- OR2M4 | c.300G>T p.Q100H | Missense Mutation (SNP) | VAF 66/91 reads (73%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as COSV100141291; called by muse, mutect2, varscan2
- OR2T6 | c.447G>T p.W149C | Missense Mutation (SNP) | VAF 57/83 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100861571; called by muse, mutect2, varscan2
- OR4C12 | c.776C>A p.S259* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as COSV100078546, COSV58859522, COSV58860758; called by mutect2, varscan2
- OR51G2 | c.103C>A p.P35T | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV100432157; called by muse, mutect2, varscan2
- OR51V1 | c.449C>A p.T150N | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as COSV100343393; called by muse, mutect2, varscan2
- OR8B2 | c.929G>A p.R310K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV66664137; called by muse, mutect2
- OR8H2 | c.671C>A p.T224N | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.25); catalogued as COSV100542362; called by muse, mutect2, varscan2
- OR9Q1 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs376251325, COSV100110063; called by muse, mutect2, varscan2
- OTOGL | c.5606G>A p.S1869N (on ENST00000547103; = p.S1860N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV100087370; called by muse, mutect2
- PAAF1 | c.340G>C p.G114R | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs374237947, COSV60154534, COSV60155919; called by mutect2, varscan2
- PCDH17 | c.2203A>C p.K735Q | Missense Mutation (SNP) | VAF 48/75 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100931708; called by muse, mutect2, varscan2
- PCED1B | c.1220G>A p.G407D | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.321); catalogued as COSV101423656; called by muse, mutect2, varscan2
- PDZD8 | c.2884G>T p.D962Y | Missense Mutation (SNP) | VAF 108/180 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs151329411; called by muse, mutect2, varscan2
- PEG3 | c.2031A>T p.K677N | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV99689260; called by muse, mutect2, varscan2
- PGM3 | c.40G>T p.A14S | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.358); catalogued as rs760545832, COSV99392418; called by muse, mutect2, varscan2
- PIGG | c.889G>C p.E297Q | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as COSV56320322; called by muse, mutect2, varscan2
- PITPNC1 | c.212G>T p.W71L | Missense Mutation (SNP) | VAF 45/71 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100083572; called by muse, mutect2, varscan2
- PKDREJ | c.3178G>A p.V1060M | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV99479022; called by muse, mutect2
- PLK1 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as COSV99891684; called by muse, mutect2, varscan2
- POU3F4 | c.779A>T p.D260V | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100937272; called by muse, mutect2, varscan2
- PRDM9 | c.138G>T p.W46C | Missense Mutation (SNP) | VAF 151/230 reads (66%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99690566; called by muse, mutect2, varscan2
- QARS1 | c.1574G>T p.R525L | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1363549666, COSV100070086, COSV60275316; called by muse, mutect2, varscan2
- R3HDM4 | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.017); catalogued as COSV100846435; called by muse, mutect2, varscan2
- RADX | c.1423C>T p.P475S | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV100998857; called by muse, mutect2, varscan2
- RAI1 | c.3886G>T p.E1296* | Nonsense Mutation (SNP) | VAF 74/122 reads (61%) | catalogued as COSV99884243; called by muse, mutect2, varscan2
- RANBP2 | c.9185C>T p.T3062I | Missense Mutation (SNP) | VAF 46/257 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs1343299424, COSV99312325; called by muse, mutect2, varscan2
- RGL1 | c.730G>A p.D244N (on ENST00000360851 / NM_001297672.2; = p.D279N on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/87 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100486995; called by muse, mutect2, varscan2
- RNF6 | c.1837A>T p.N613Y | Missense Mutation (SNP) | VAF 45/77 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV100644644; called by muse, mutect2, varscan2
- ROPN1L | c.200C>T p.T67I | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99928672; called by muse, mutect2, varscan2
- RRP15 | c.4G>C p.A2P | Missense Mutation (SNP) | VAF 81/106 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); catalogued as COSV100860758; called by muse, mutect2, varscan2
- SERTAD2 | c.806C>T p.S269L | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as COSV100512206, COSV57640628; called by muse, mutect2, varscan2
- SETD2 | c.4496G>T p.C1499F | Missense Mutation (SNP) | VAF 28/36 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV100339208, COSV57452397; called by muse, mutect2, varscan2
- SEZ6L2 | c.409C>G p.P137A | Missense Mutation (SNP) | VAF 42/67 reads (63%) | SIFT tolerated (0.23); PolyPhen benign (0.091); catalogued as COSV100435530; called by muse, mutect2, varscan2
- SEZ6L2 | c.408C>A p.S136R | Missense Mutation (SNP) | VAF 41/65 reads (63%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100435531; called by muse, mutect2, varscan2
- SHOX | c.577G>T p.A193S | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT tolerated (0.13); PolyPhen benign (0.089); catalogued as COSV100479115; called by muse, mutect2, varscan2
- SIGLEC1 | c.3253C>G p.Q1085E | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV99166596; called by muse, mutect2, varscan2
- SLC12A7 | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.206); catalogued as COSV99370052; called by muse, varscan2
- SLC17A3 | c.725A>G p.Y242C | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100399233; called by muse, mutect2, varscan2
- SLC19A3 | c.1171G>A p.V391I | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.155); catalogued as COSV99295886; called by muse, mutect2, varscan2
- SLC1A7 | c.1226G>A p.S409N | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV101020167; called by muse, mutect2
- SLC22A13 | c.258C>A p.F86L | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV100314577; called by muse, mutect2, varscan2
- SLC25A13 | c.1774C>T p.Q592* | Nonsense Mutation (SNP) | VAF 73/163 reads (45%) | catalogued as COSV99673741; called by muse, mutect2, varscan2
- SLC25A31 | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.696); catalogued as COSV55417690, COSV55418534; called by muse, mutect2, varscan2
- SLC27A1 | c.1936C>T p.L646F | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99393397, COSV99393652; called by muse, mutect2, varscan2
- SLC35E1 | c.983G>T p.G328V | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101290779; called by muse, mutect2
- SLC66A2 | c.466G>T p.V156L | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV100673823; called by muse, mutect2, varscan2
- SLITRK1 | c.91T>G p.C31G | Missense Mutation (SNP) | VAF 41/71 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100999977; called by muse, mutect2, varscan2
- SLITRK3 | c.2048G>A p.R683Q | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.953); catalogued as rs756131997, COSV53845789; called by muse, mutect2, varscan2
- SLTM | c.954G>T p.E318D | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as COSV99989215; called by muse, mutect2, varscan2
- SLX4 | c.4585C>T p.Q1529* | Nonsense Mutation (SNP) | VAF 95/152 reads (63%) | catalogued as rs1237224833, COSV99568133; called by muse, mutect2, varscan2
- SMARCA2 | c.1129A>T p.T377S | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.97); catalogued as COSV100571219; called by muse, mutect2, varscan2
- SMR3A | c.400C>A p.P134T | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.3); catalogued as COSV99895711, COSV99895834; called by muse, mutect2, varscan2
- SNIP1 | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.034); catalogued as rs1050240331, COSV56166213; called by muse, mutect2, varscan2
- SOHLH1 | c.109C>G p.R37G | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV100040211, COSV100040239, COSV53681290; called by muse, mutect2, varscan2
- SPEF2 | c.130C>G p.Q44E | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99214331; called by muse, mutect2
- SPINT2 | c.625T>A p.L209M | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV100007567; called by muse, mutect2
- SRRM2 | c.1540C>T p.R514C | Missense Mutation (SNP) | VAF 55/85 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs753511984, COSV100070965; called by muse, mutect2, varscan2
- ST8SIA1 | c.603G>T p.W201C | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV99683240; called by muse, mutect2, varscan2
- STING1 | c.337G>C p.V113L | Missense Mutation (SNP) | VAF 54/91 reads (59%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100423457; called by muse, mutect2, varscan2
- STON1 | c.38A>T p.D13V | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV100561929; called by muse, mutect2, varscan2
- SYCE2 | c.506G>C p.R169T | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.086); catalogued as COSV99535950; called by muse, mutect2, varscan2
- SYNDIG1 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs760987356, COSV100965300; called by muse, mutect2, varscan2
- TANC1 | c.1281G>C p.L427F | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99714186; called by muse, mutect2, varscan2
- TANC1 | c.1400G>C p.S467T | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV99714188; called by muse, mutect2, varscan2
- TBC1D12 | c.2195C>T p.S732L | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as rs750546732, COSV56558545; called by muse, mutect2, varscan2
- TGFBR3 | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53025203; called by muse, mutect2, varscan2
- THEMIS | c.920T>A p.I307N | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100965421, COSV64069356; called by muse, mutect2, varscan2
- TIGIT | c.654C>A p.D218E | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.255); catalogued as COSV101048102; called by muse, mutect2
- TLR4 | c.331G>T p.G111* (on ENST00000355622 / NM_138554.5; = p.G71* on NM_003266.4) | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as COSV100790612, COSV100790618; called by mutect2, varscan2
- TLR4 | c.332G>T p.G111V (on ENST00000355622 / NM_138554.5; = p.G71V on NM_003266.4) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100790657, COSV62922591, COSV62923206; called by muse, mutect2, varscan2
- TMEM132B | c.2051C>A p.S684Y | Missense Mutation (SNP) | VAF 63/97 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV100169930; called by muse, mutect2, varscan2
- TMEM248 | c.274G>C p.G92R | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.84); PolyPhen benign (0.313); catalogued as COSV100447377, COSV58577390; called by muse, mutect2, varscan2
- TMPRSS15 | c.119G>T p.C40F | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV99518177; called by muse, mutect2, varscan2
- TNFRSF10B | c.711G>A p.W237* | Nonsense Mutation (SNP) | VAF 45/68 reads (66%) | catalogued as COSV99375423; called by muse, mutect2, varscan2
- TRIOBP | c.13C>A p.P5T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100730911; called by muse, mutect2, varscan2
- TRIP13 | c.1088A>T p.E363V | Missense Mutation (SNP) | VAF 85/279 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV99386419; called by muse, mutect2, varscan2
- TRPC4 | c.506C>A p.P169H | Missense Mutation (SNP) | VAF 53/79 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100157045; called by muse, mutect2, varscan2
- TTC16 | c.2483C>T p.S828F | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs1243705016, COSV100263003; called by muse, mutect2, varscan2
- TTN | c.34729G>T p.V11577L (on ENST00000591111; = p.V10650L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/110 reads (24%) | PolyPhen benign (0); catalogued as rs72650062; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBGCP6 | c.2371C>G p.R791G | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99955723; called by muse, mutect2, varscan2
- UBXN11 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as rs767971948, COSV100122668; called by muse, mutect2, varscan2
- UGT1A8 | c.319T>A p.S107T | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0.026); catalogued as COSV100990656; called by muse, mutect2, varscan2
- UMODL1 | c.1928C>A p.P643H (on ENST00000408910 / NM_001004416.2; = p.P771H on NM_173568.3) | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.753); catalogued as COSV100210706; called by muse, mutect2, varscan2
- UROC1 | c.646C>A p.Q216K | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as COSV52031061, COSV99331598; called by muse, mutect2, varscan2
- USH2A | c.4955del p.P1652Rfs*13 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | catalogued as COSV100237956; called by mutect2, pindel, varscan2
- USP35 | c.2083G>T p.E695* | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | catalogued as COSV101489109; called by muse, mutect2, varscan2
- USP5 | c.1086C>G p.F362L | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.378); catalogued as rs1442276604, COSV99978714; called by muse, mutect2, varscan2
- VNN1 | c.959C>A p.A320D | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.452); catalogued as COSV100907746; called by muse, varscan2
- VOPP1 | c.171A>G p.I57M | Missense Mutation (SNP) | VAF 61/126 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs750529839, COSV99567281; called by muse, mutect2, varscan2
- VPS13C | c.3776C>A p.T1259N (on ENST00000644861 / NM_020821.3; = p.T1216N on NM_017684.5) | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0.014); catalogued as COSV99828775; called by muse, mutect2, varscan2
- VWA7 | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 115/155 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100991862; called by muse, mutect2, varscan2
- WBP11 | c.1408C>T p.P470S | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.407); catalogued as COSV99660738; called by muse, mutect2, varscan2
- WDR72 | c.2658A>T p.R886S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV100854591; called by muse, mutect2, varscan2
- WFDC12 | c.198T>G p.C66W | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100859089; called by muse, mutect2, varscan2
- XDH | c.1928G>T p.G643V | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV101052245; called by muse, mutect2, varscan2
- XKR3 | c.433C>G p.L145V | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT tolerated (0.75); PolyPhen benign (0.127); catalogued as COSV100509285, COSV58885255; called by muse, mutect2, varscan2
- YAP1 | c.803C>G p.A268G (on ENST00000282441 / NM_001130145.3; = p.A230G on NM_006106.5) | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.263); catalogued as COSV56778354, COSV99176162; called by muse, mutect2, varscan2
- Z83844.2 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.89); catalogued as rs747446460, COSV99312872; called by muse, mutect2, varscan2
- ZFHX3 | c.3437C>G p.S1146C | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as COSV99213239; called by muse, mutect2, varscan2
- ZFP28 | c.2486C>T p.A829V | Missense Mutation (SNP) | VAF 68/320 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100019640; called by muse, mutect2, varscan2
- ZFR | c.2149C>T p.R717C | Missense Mutation (SNP) | VAF 53/81 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs764560160, COSV99416102; called by muse, mutect2, varscan2
- ZIM2 | c.1513C>G p.R505G | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.469); catalogued as COSV99689256; called by muse, mutect2, varscan2
- ZNF28 | c.1475A>G p.E492G | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100354529; called by muse, mutect2, varscan2
- ZNF318 | c.2541G>T p.K847N | Missense Mutation (SNP) | VAF 147/247 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100546254; called by muse, mutect2, varscan2
- ZNF347 | c.1721G>T p.C574F | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100498322, COSV100498404; called by muse, mutect2, varscan2
- ZNF347 | c.311A>T p.K104I | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.125); catalogued as COSV100498323; called by muse, mutect2, varscan2
- ZNF582 | c.1399G>A p.V467I | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs141898302, COSV56733366; called by muse, mutect2, varscan2
- ZNF585B | c.1925C>G p.A642G | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.121); catalogued as COSV100459479; called by muse, mutect2
- ZNF600 | c.911G>C p.C304S | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1465481277, COSV100593012; called by muse, mutect2, varscan2
- ZNF773 | c.989C>G p.P330R | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99989383; called by muse, mutect2, varscan2
- ZNF813 | c.1209A>T p.R403S | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.757); catalogued as COSV101124882; called by muse, mutect2
- ABCC9 | c.2551A>G p.M851V | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2
- AHNAK2 | c.1921_1937del p.S641Kfs*8 | Frame Shift Del (DEL) | VAF 79/243 reads (33%) | called by mutect2, pindel, varscan2
- CEP250 | c.40del p.Q14Sfs*29 | Frame Shift Del (DEL) | VAF 4/9 reads (44%) | called by mutect2, varscan2
- CHD9 | c.4275dup p.W1426Mfs*3 | Frame Shift Ins (INS) | VAF 17/114 reads (15%) | called by mutect2, pindel, varscan2
- FCGBP | c.5755C>A p.L1919I | Missense Mutation (SNP) | VAF 18/346 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- INPP1 | c.948_990del p.D316Efs*2 | Frame Shift Del (DEL) | VAF 27/95 reads (28%) | called by mutect2, pindel
- MAP3K1 | c.2840_2841del p.T947Nfs*56 | Frame Shift Del (DEL) | VAF 23/38 reads (61%) | called by muse*, mutect2, varscan2*
- MUC16 | c.27244del p.Q9082Kfs*38 | Frame Shift Del (DEL) | VAF 43/122 reads (35%) | called by mutect2, pindel, varscan2
- NFATC2IP | c.740_748del p.E247_E249del | In Frame Del (DEL) | VAF 8/86 reads (9%) | called by mutect2, pindel
- OPA1 | c.1722_1723delinsT p.E574Dfs*11 (on ENST00000361510 / NM_130837.3; = p.E519Dfs*11 on NM_015560.3) | Frame Shift Del (DEL) | VAF 28/132 reads (21%) | called by pindel, varscan2*
- OR2Z1 | c.445dup p.W149Lfs*32 | Frame Shift Ins (INS) | VAF 56/173 reads (32%) | called by mutect2, pindel, varscan2
- OTOA | c.237del p.N80Mfs*31 | Frame Shift Del (DEL) | VAF 46/92 reads (50%) | called by mutect2, pindel, varscan2
- PGM5 | c.1013G>T p.R338M | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPDC1 | c.207_220del p.R70Gfs*5 (on ENST00000375360 / NM_177995.3; = p.R122Gfs*5 on NM_152422.4) | Frame Shift Del (DEL) | VAF 13/50 reads (26%) | called by mutect2, pindel, varscan2
- SLC28A1 | c.1559del p.G520Afs*35 | Frame Shift Del (DEL) | VAF 29/176 reads (16%) | called by mutect2, pindel, varscan2
- SLC5A11 | c.1918_1927del p.E640* | Frame Shift Del (DEL) | VAF 80/292 reads (27%) | called by mutect2, pindel, varscan2
- SNAPC4 | c.3029_3040del p.G1010_I1014delinsV | In Frame Del (DEL) | VAF 4/24 reads (17%) | called by mutect2, pindel
- SV2A | c.1468del p.E490Sfs*3 | Frame Shift Del (DEL) | VAF 97/253 reads (38%) | called by mutect2, pindel, varscan2
- TRIM43 | c.152A>T p.N51I | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- XRN2 | c.110A>G p.D37G | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2
- ZSCAN26 | c.1038T>A p.N346K (on ENST00000623276 / NM_001111039.2; = p.N212K on NM_152736.5) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.928); called by muse, mutect2
- ABCB7 | c.1881C>G p.P627= (on ENST00000373394 / NM_001271696.3; = p.P628= on NM_004299.6) | Silent (SNP) | VAF 11/15 reads (73%) | catalogued as COSV99504456; called by muse, mutect2, varscan2
- ACSM2A | c.828T>C p.P276= (on ENST00000219054; = p.P197= on NM_001308169.2) | Silent (SNP) | VAF 103/146 reads (71%) | catalogued as COSV99525335; called by muse, mutect2, varscan2
- ADAMTS12 | c.438A>T p.L146= | Silent (SNP) | VAF 39/125 reads (31%) | catalogued as COSV100711110; called by muse, mutect2, varscan2
- ADPRH | c.813G>A p.G271= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV100813326; called by muse, mutect2, varscan2
- AJAP1 | c.75C>A p.A25= | Silent (SNP) | VAF 116/227 reads (51%) | catalogued as COSV100981822; called by muse, mutect2, varscan2
- AP3D1 | c.1371C>T p.S457= | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as rs780238026, COSV100642756; called by muse, mutect2, varscan2
- ATAT1 | c.942C>A p.G314= | Silent (SNP) | VAF 106/150 reads (71%) | catalogued as COSV99528015; called by muse, mutect2, varscan2
- CALHM2 | c.51G>A p.K17= | Silent (SNP) | VAF 19/101 reads (19%) | catalogued as COSV99588665, COSV99588861; called by muse, mutect2, varscan2
- CAP1 | c.654C>T p.S218= | Silent (SNP) | VAF 22/30 reads (73%) | catalogued as rs569531431, COSV100472443; called by muse, mutect2, varscan2
- CD3G | c.369C>T p.I123= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as rs769843997, COSV52675530, COSV99416684; called by muse, mutect2, varscan2
- CLCN5 | c.978C>A p.G326= | Silent (SNP) | VAF 32/43 reads (74%) | catalogued as COSV100260222; called by muse, mutect2, varscan2
- CNOT1 | c.5790C>G p.A1930= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV99800435; called by muse, mutect2, varscan2
- COL22A1 | c.3804A>G p.P1268= | Silent (SNP) | VAF 92/144 reads (64%) | catalogued as COSV100278839; called by muse, varscan2
- COL2A1 | c.2685C>G p.A895= | Silent (SNP) | VAF 56/110 reads (51%) | catalogued as COSV100476705; called by muse, mutect2, varscan2
- DCAF4L1 | c.468A>G p.A156= | Silent (SNP) | VAF 20/120 reads (17%) | catalogued as rs551460334, COSV100295781; called by muse, mutect2, varscan2
- DGKI | c.648C>G p.V216= | Silent (SNP) | VAF 38/196 reads (19%) | catalogued as COSV99935102; called by muse, mutect2, varscan2
- DNAH9 | c.945G>C p.P315= | Silent (SNP) | VAF 21/25 reads (84%) | catalogued as COSV99306277; called by muse, mutect2, varscan2
- DUOX1 | c.393C>T p.D131= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as rs770187541, COSV100368072; called by muse, mutect2, varscan2
- EDC4 | c.2421C>G p.T807= | Silent (SNP) | VAF 52/100 reads (52%) | catalogued as COSV100197673; called by muse, mutect2, varscan2
- EVX2 | c.852G>T p.L284= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as COSV100420706; called by muse, mutect2
- F5 | c.3006T>C p.P1002= | Silent (SNP) | VAF 94/216 reads (44%) | catalogued as COSV100889137; called by muse, mutect2, varscan2
- FAM83D | c.600T>C p.S200= | Silent (SNP) | VAF 41/105 reads (39%) | catalogued as COSV99465267; called by muse, mutect2, varscan2
- FGD6 | c.243G>C p.G81= | Silent (SNP) | VAF 68/133 reads (51%) | catalogued as COSV100676641; called by muse, mutect2, varscan2
- FNBP4 | c.57G>T p.P19= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs888667018, COSV99771726; called by muse, mutect2
- FOXP2 | c.993G>C p.S331= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV100646128, COSV63488109; called by muse, mutect2
- GRIK2 | c.1608T>A p.L536= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as COSV100026849; called by muse, varscan2
- GRM3 | c.2256T>A p.T752= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as COSV100862599; called by muse, mutect2, varscan2
- GSS | c.1047G>A p.Q349= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as rs772123367, COSV99404460; called by muse, mutect2, varscan2
- HSPA9 | c.1428T>A p.A476= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as COSV99785537; called by muse, mutect2, varscan2
- IGSF9 | c.1959G>T p.L653= (on ENST00000368094 / NM_001135050.2; = p.L637= on NM_020789.4) | Silent (SNP) | VAF 25/353 reads (7%) | catalogued as COSV100829636; called by muse, mutect2
- IL12RB1 | c.36C>G p.L12= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV100443058; called by muse, mutect2, varscan2
- INA | c.894G>A p.A298= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV100878551; called by muse, mutect2, varscan2
- ITPR2 | c.276A>G p.L92= | Silent (SNP) | VAF 24/38 reads (63%) | catalogued as rs1234502985, COSV99659394; called by muse, mutect2
- KCND2 | c.921T>A p.S307= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV100476379; called by muse, mutect2, varscan2
- KLK6 | c.271C>A p.R91= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV100037716; called by muse, mutect2, varscan2
- KRIT1 | c.1155A>T p.T385= | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as COSV100388804; called by muse, mutect2, varscan2
- LRP1B | c.12825T>C p.C4275= | Silent (SNP) | VAF 60/148 reads (41%) | catalogued as COSV101257752; called by muse, mutect2, varscan2
- LRRN3 | c.1707T>A p.A569= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV100071214; called by muse, mutect2, varscan2
- MEI1 | c.1746C>G p.L582= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV100300046, COSV55902614; called by muse, mutect2, varscan2
- MILR1 | c.888G>A p.P296= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs146008785; called by muse, mutect2
- NLRP1 | c.1503T>C p.I501= | Silent (SNP) | VAF 34/58 reads (59%) | catalogued as COSV99334420; called by muse, mutect2, varscan2
- NMRK2 | c.246C>A p.A82= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV99396377; called by muse, mutect2, varscan2
- NRXN2 | c.1929A>C p.P643= | Silent (SNP) | VAF 26/44 reads (59%) | catalogued as COSV99634599; called by muse, mutect2, varscan2
- NUTM1 | c.2446T>C p.L816= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as rs1474855773, COSV100149033; called by muse, mutect2, varscan2
- OCA2 | c.774C>T p.D258= | Silent (SNP) | VAF 3/41 reads (7%) | catalogued as rs757789602, COSV100667034; called by muse, mutect2
- OR4A15 | c.762C>T p.F254= | Silent (SNP) | VAF 64/128 reads (50%) | catalogued as COSV59033723, COSV59035423; called by muse, mutect2, varscan2
- OR4A5 | c.114G>T p.V38= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as COSV100157134; called by muse, mutect2, varscan2
- OSBPL1A | c.105T>G p.A35= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV100111963; called by muse, mutect2, varscan2
- P2RY14 | c.844C>T p.L282= | Silent (SNP) | VAF 14/150 reads (9%) | catalogued as COSV99853507; called by muse, mutect2
- PAPPA2 | c.4386G>T p.V1462= | Silent (SNP) | VAF 47/114 reads (41%) | catalogued as COSV100868277; called by muse, mutect2, varscan2
- PLCH1 | c.3120G>T p.G1040= (on ENST00000340059 / NM_001130960.2; = p.G1032= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 60/174 reads (34%) | catalogued as COSV100397142; called by muse, mutect2, varscan2
- POU4F1 | c.1203G>T p.V401= | Silent (SNP) | VAF 37/70 reads (53%) | catalogued as COSV101020563; called by muse, mutect2, varscan2
- PPFIA3 | c.2790T>C p.L930= | Silent (SNP) | VAF 18/105 reads (17%) | catalogued as rs923056492, COSV100494986; called by muse, mutect2, varscan2
- PREX1 | c.3540C>G p.V1180= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV100906448; called by muse, mutect2
- PROC | c.1194C>T p.C398= | Silent (SNP) | VAF 260/391 reads (66%) | catalogued as rs146028808, CM036049; called by muse, mutect2, varscan2
- PRRC2C | c.4425G>T p.G1475= (on ENST00000367742; = p.G1473= on NM_015172.4) | Silent (SNP) | VAF 29/108 reads (27%) | catalogued as rs1484353118, COSV100145423; called by muse, mutect2, varscan2
- PTPRN2 | c.2556C>T p.G852= | Silent (SNP) | VAF 42/75 reads (56%) | catalogued as COSV66104976; called by muse, mutect2, varscan2
- RASGRF1 | c.1170G>T p.L390= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV101369659; called by muse, mutect2, varscan2
- SEMA3E | c.1263A>G p.K421= | Silent (SNP) | VAF 15/117 reads (13%) | catalogued as COSV57086018, COSV57093446; called by muse, mutect2, varscan2
- SENP1 | c.156A>T p.G52= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV99136981; called by muse, mutect2, varscan2
- SH3RF3 | c.717A>T p.T239= | Silent (SNP) | VAF 50/84 reads (60%) | catalogued as COSV100513105; called by muse, mutect2, varscan2
- SIDT1 | c.1041T>C p.N347= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV99334116; called by muse, mutect2, varscan2
- SIGLEC8 | c.1434A>G p.R478= | Silent (SNP) | VAF 44/116 reads (38%) | catalogued as COSV100367288; called by muse, mutect2, varscan2
- SLC22A3 | c.1218A>T p.R406= | Silent (SNP) | VAF 86/153 reads (56%) | catalogued as COSV99279041; called by muse, varscan2
- SLC6A5 | c.900C>T p.A300= | Silent (SNP) | VAF 36/83 reads (43%) | catalogued as COSV100116953; called by muse, mutect2, varscan2
- SLCO1C1 | c.420A>G p.R140= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as rs748780363, COSV99859239; called by muse, mutect2
- SREBF2 | c.2601C>A p.A867= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV100761442, COSV63332256; called by muse, mutect2
- SYNE1 | c.4188T>A p.A1396= (on ENST00000367255 / NM_182961.4; = p.A1403= on NM_033071.3) | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV99567409; called by muse, mutect2
- TMEM132B | c.2052C>G p.S684= | Silent (SNP) | VAF 61/96 reads (64%) | catalogued as COSV100169931; called by muse, mutect2, varscan2
- TRBV27 | c.72C>T p.T24= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as rs775662193; called by muse, mutect2, varscan2
- UGT1A1 | c.450G>T p.T150= | Silent (SNP) | VAF 40/96 reads (42%) | catalogued as COSV100530368; called by muse, mutect2, varscan2
- UGT3A1 | c.255T>C p.H85= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV99954875; called by muse, mutect2, varscan2
- XRN1 | c.2406A>G p.T802= | Silent (SNP) | VAF 34/96 reads (35%) | catalogued as COSV99378190; called by muse, mutect2, varscan2
- YY2 | c.1065A>C p.S355= | Silent (SNP) | VAF 73/201 reads (36%) | catalogued as COSV100810777; called by muse, mutect2, varscan2
- ZIM2 | c.1512C>G p.G504= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV55631065, COSV99689257; called by muse, mutect2, varscan2
- ZNF331 | c.1137C>A p.G379= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV53476892, COSV53477379, COSV99467054; called by muse, mutect2, varscan2
- ZNF574 | c.1650C>T p.P550= | Silent (SNP) | VAF 42/244 reads (17%) | catalogued as rs1464573535, COSV99726178, COSV99726203; called by muse, mutect2, varscan2
- ZNF626 | c.1188C>A p.P396= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV101656992; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503639 G>T | 5'Flank (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- CEP295 | chr11:93735205 G>A | 3'Flank (SNP) | VAF 4/32 reads (13%) | catalogued as rs760390988; called by mutect2, varscan2
- CLN5 | chr13:76992083 T>G | 5'Flank (SNP) | VAF 14/20 reads (70%) | catalogued as COSV101080334; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152445531 C>A | 3'Flank (SNP) | VAF 21/70 reads (30%) | called by muse, mutect2, varscan2
- FOLH1B | n.940C>G | RNA (SNP) | VAF 13/42 reads (31%) | called by muse, mutect2, varscan2
- IGHG1 | chr14:105737809 G>T | 3'Flank (SNP) | VAF 24/69 reads (35%) | called by muse, mutect2, varscan2
- MIR517B | n.30T>G | RNA (SNP) | VAF 47/137 reads (34%) | catalogued as rs759408812; called by muse, mutect2, varscan2
- NDUFA13 | chr19:19516197 A>T | 5'Flank (SNP) | VAF 32/65 reads (49%) | catalogued as COSV99389106; called by muse, mutect2, varscan2
- RPL13A | c.402+110G>A | Intron (SNP) | VAF 48/163 reads (29%) | catalogued as rs1371258683, COSV99201307; called by muse, mutect2, varscan2
- SFTA3 | n.929G>A | RNA (SNP) | VAF 30/140 reads (21%) | catalogued as rs1301300849, COSV101410195; called by muse, mutect2, varscan2
- TECR | c.-61T>C | 5'UTR (SNP) | VAF 22/61 reads (36%) | catalogued as COSV99295598; called by muse, mutect2, varscan2
- ZNF467 | chr7:149776074 G>A | 5'Flank (SNP) | VAF 10/28 reads (36%) | catalogued as rs372265232; called by muse, mutect2, varscan2
